Somatic mutation profile of tumor specimen TARGET-40-PASUUH-01A (aliquot TARGET-40-PASUUH-01A-01D) from TARGET case TARGET-40-PASUUH, project TARGET-OS (Osteosarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Osteosarcoma, NOS; Tissue or organ of origin: Long bones of lower limb and associated joints; Age at diagnosis: 14.1 years (5,143 days).
Specimen TARGET-40-PASUUH-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 88ea2912-f6a6-4f04-805f-0bf36c832733.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-40-PASUUH-10A (Blood Derived Normal), aliquot TARGET-40-PASUUH-10A-01Y; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cf3d490f-c501-4929-8532-55da37914368

The open-access MAF lists 40 somatic variants for this specimen: 18 protein-altering or splice-affecting, 8 silent, 14 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 17, Intron 10, Silent 8, RNA 3, Nonsense Mutation 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SMARCA4 | c.3608G>A p.R1203H | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.772); catalogued as rs770680174, CM1310765, COSV60803832; ClinVar: pathogenic / likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- CDH8 | c.1081C>T p.H361Y | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT tolerated (0.28); PolyPhen benign (0.036); catalogued as COSV54872935; called by muse, mutect2, varscan2
- DZIP1 | c.208C>T p.R70W | Missense Mutation (SNP) | VAF 6/118 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV61270751; called by muse, mutect2
- EVPL | c.5349G>C p.E1783D | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.057); catalogued as rs1215089367; called by muse, mutect2, varscan2
- PABPC1 | c.1336C>T p.P446S | Missense Mutation (SNP) | VAF 12/190 reads (6%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as rs938171318; called by muse, mutect2
- ARPC5 | c.230G>A p.S77N | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- BMP10 | c.150C>A p.D50E | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.76); called by mutect2, varscan2
- DNAH3 | c.4724C>T p.S1575F | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- GRIA1 | c.1090T>A p.Y364N | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- GRM5 | c.1510A>T p.S504C | Missense Mutation (SNP) | VAF 23/40 reads (58%) | SIFT deleterious (0.01); PolyPhen benign (0.087); called by muse, mutect2, varscan2
- KCNS3 | c.1429G>T p.E477* | Nonsense Mutation (SNP) | VAF 21/57 reads (37%) | called by muse, mutect2, varscan2
- LRRFIP1 | c.2092G>A p.E698K (on ENST00000392000 / NM_001137552.2; = p.E674K on NM_004735.4) | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- MALL | c.166C>G p.Q56E | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.142); called by muse, mutect2
- PCDH11X | c.2566A>T p.T856S | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT tolerated (0.44); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- POSTN | c.620A>G p.N207S | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- THBS1 | c.758C>A p.A253D | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.655); called by muse, mutect2, varscan2
- TMEM165 | c.850G>A p.A284T | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ZNF33A | c.1607A>C p.K536T (on ENST00000458705 / NM_006974.3; = p.K537T on NM_006954.2) | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CDC42BPB | c.2391G>A p.L797= | Silent (SNP) | VAF 3/26 reads (12%) | called by muse, mutect2
- FCHSD1 | c.1962G>A p.L654= | Silent (SNP) | VAF 12/31 reads (39%) | called by muse, mutect2, varscan2
- IQGAP1 | c.477G>A p.L159= | Silent (SNP) | VAF 11/74 reads (15%) | called by muse, mutect2, varscan2
- KCTD19 | c.855G>A p.P285= | Silent (SNP) | VAF 6/30 reads (20%) | catalogued as rs762961836, COSV100430985; called by muse, mutect2, varscan2
- RYBP | c.465C>T p.N155= | Silent (SNP) | VAF 35/50 reads (70%) | catalogued as rs770940786, COSV72180803; called by muse, mutect2, varscan2
- SLC25A1 | c.813G>A p.G271= | Silent (SNP) | VAF 6/53 reads (11%) | catalogued as rs1555922286; called by muse, mutect2
- SLC9C1 | c.1743A>T p.L581= | Silent (SNP) | VAF 9/19 reads (47%) | catalogued as COSV59887890; called by muse, mutect2, varscan2
- ZNF513 | c.1569G>A p.R523= | Silent (SNP) | VAF 11/28 reads (39%) | called by mutect2, varscan2
- APBB3 | c.632+13C>G | Intron (SNP) | VAF 6/54 reads (11%) | called by mutect2, varscan2
- ARHGEF40 | c.2640+22T>A | Intron (SNP) | VAF 11/78 reads (14%) | called by muse, mutect2, varscan2
- BX322639.1 | n.1666G>C | RNA (SNP) | VAF 4/25 reads (16%) | called by muse, mutect2, varscan2
- CENPF | c.-42+2635G>T | Intron (SNP) | VAF 12/46 reads (26%) | called by muse, mutect2, varscan2
- FAM9B | c.28+11C>T | Intron (SNP) | VAF 8/35 reads (23%) | called by muse, mutect2, varscan2
- FCRLA | c.149-10C>T | Intron (SNP) | VAF 6/64 reads (9%) | catalogued as rs867667212; called by muse, mutect2
- IKZF4 | c.*44C>G | 3'UTR (SNP) | VAF 32/103 reads (31%) | called by muse, mutect2, varscan2
- KLK3 | c.631-245A>G | Intron (SNP) | VAF 4/11 reads (36%) | called by muse, mutect2, varscan2
- LIMCH1 | c.935+7408A>T | Intron (SNP) | VAF 12/130 reads (9%) | called by muse, mutect2
- MPRIP | c.2163+3972G>A | Intron (SNP) | VAF 9/102 reads (9%) | catalogued as rs969996051; called by muse, mutect2, varscan2
- MUC20P1 | n.831T>C | RNA (SNP) | VAF 8/26 reads (31%) | catalogued as rs28461405; called by mutect2, varscan2
- RPSAP8 | n.101G>T | RNA (SNP) | VAF 12/36 reads (33%) | called by muse, mutect2, varscan2
- SVOP | c.971+49C>A | Intron (SNP) | VAF 28/61 reads (46%) | called by muse, mutect2, varscan2
- THRA | c.1110+30C>T | Intron (SNP) | VAF 7/62 reads (11%) | called by muse, mutect2, varscan2
